TARGET case TARGET-15-SJMPAL040025 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e180177-afdd-43ac-bd65-3d15ed4aa1cd

Demographics
Sex at birth: female; Age at index: 9 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 9.1 years (3,319 days); Year of diagnosis: 2008; Days to last follow up: 2,130 days (5.8 years).

Follow-up (1 entry)
- Days to follow up: 2,130 days (5.8 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,130; Year of follow up: 2014.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 14.8 ×10³/µL.

Biospecimens (5 samples)
- Samples TARGET-15-SJMPAL040025-09A, TARGET-15-SJMPAL040025-09A.1, TARGET-15-SJMPAL040025-09A.2, TARGET-15-SJMPAL040025-09B (4 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL040025-14A.1: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 2130
- Protocol: Japan (JACLS)
- WBC at Diagnosis: 14.8
- Initial Therapy: ALL
- Karyotype: 46,XX,del(9q11) [3/9], 47,XX,del(9q11), +mar [2/9], 46,XX [4/9]
- WHO ALAL Classification: B/M
- WHO Dx: B/M
